Gene-level copy-number profile of tumor specimen TCGA-EE-A17Y-06A from TCGA case TCGA-EE-A17Y, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.6 years (25,788 days).
Specimen TCGA-EE-A17Y-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.91a028da-5d97-4d8f-a28c-fc7a536696a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A17Y-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4141da3f-c424-465e-946b-ad792457109a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 2,541; copy number 2: 17,016; copy number 3: 11,265; copy number 4: 23,390; copy number 5: 4,172; copy number 6: 1,376; copy number 7: 34; copy number 9: 1; copy number 10: 1; copy number 15: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A17Y-06A-11D-A194-01): tumor purity 0.54, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:65,589,566–65,640,177, 2 genes (within-gene range 0–3): AC007389.2, AC007389.3.
- chr3:186,046,314–186,362,234, 4 genes: ETV5, Metazoa_SRP, ETV5-AS1, DGKG.
- chr9:21,929,457–22,128,103, 9 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:87,817,928–87,971,930, 6 genes: CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,672,823–43,674,591, 2 genes, copy number 15: AC139365.2, AC139365.1.
- chr11:50,409,042–50,422,316, 1 gene, copy number 9: AC024405.1.
- chr12:37,575,587–37,576,384, 1 gene, copy number 10: ZNF970P.

Autosomal genes at a single copy (total copy number 1): 621. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
